MMRF case MMRF_2201 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/9e899f94-e865-421c-9c1b-b0a1900079ca

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 75 years; Vital status: Dead; Days to death: 423 days (1.2 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 75.8 years (27,695 days); ISS stage: II; Days to last known disease status: 423 days (1.2 years); Days to last follow up: 423 days (1.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 8 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 423.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -7 (ECOG 1): M Protein 3.23 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.16 mg/dL; Immunoglobulin G 39.3 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 3.4 µg/mL; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 5.7 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.23 mmol/L; Albumin 32 g/L; Total Protein 9.3 g/dL; Glucose 7.21 mmol/L.
- Day 69 (ECOG 2): M Protein 2.62 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.23 mg/dL; Immunoglobulin G 29.6 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.13 g/L; Hemoglobin 6.45 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 344 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.15 mmol/L; Albumin 27 g/L; Total Protein 7.9 g/dL; Glucose 5.17 mmol/L.
- Day 176 (ECOG 2): M Protein 2.79 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 35.9 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.09 g/L; Hemoglobin 7.07 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.2 mmol/L; Albumin 29 g/L; Total Protein 8.5 g/dL; Glucose 5.23 mmol/L.
- Day 253 (ECOG 2): M Protein 2.97 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.82 mg/dL; Immunoglobulin G 43.5 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.15 g/L; Hemoglobin 6.39 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.2 mmol/L; Albumin 28 g/L; Total Protein 8.6 g/dL; Glucose 4.35 mmol/L.
- Day 344 (ECOG 2): M Protein 3.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.12 mg/dL; Immunoglobulin G 51.5 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.1 g/L; Hemoglobin 6.76 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.28 mmol/L; Albumin 28 g/L; Total Protein 9.7 g/dL; Glucose 4.79 mmol/L.

Other clinical attributes
- Day -7: Weight: 65 kg; Height: 182 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2201_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -7 days.
- Sample MMRF_2201_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -7 days.
